Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8018, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8018-01A (Primary Tumor).

Pathology Report for [REDACTED]

Addendum Discussion:

Scattered MIB-1 reactive cells are present. In the most proliferative areas, a labeling index of 5.0 % is calculated. This is an intermediate level of proliferative activity and is consistent with the generally low grade histologic features.

Addendum Diagnosis:

Oligoastrocytoma, Oligodendroglioma predominant. Low grade (WHO grade II)

- MIB-1 labeling index: 5.0%

Microscopic Discussion:

Sections demonstrate a mildly to moderately hypercellular glial neoplasm. The predominant population is microgemistocyte. Only a minority of the cells demonstrate perinuclear halos. In addition, there is a minority population with more oblong nuclei and modest eosinophilic cytoplasm. No mitotic figures are seen. There is no microvascular proliferation or necrosis.

Source: NCI Genomic Data Commons file ae464bb0-6fed-401d-b1f9-c7e8b520f511 (TCGA-HT-8018.3C1686B7-7A13-43CD-9D42-E4F564B75423.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).